Somatic mutation profile of tumor specimen 0DJVPI from CCDI case PBBXPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.3 years (3,402 days).
Specimen 0DJVPI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 712bebe2-cba8-4048-869a-f3358700d18b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVPG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96a23cfa-1a59-47c7-a9ab-d7b49f685ace

The open-access MAF lists 43 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Intron 6, 5'UTR 3, 3'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPPK1 | c.6487G>A p.E2163K | Missense Mutation (SNP) | VAF 46/621 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.074); catalogued as rs782473994; called by muse, mutect2
- ITGAV | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 52/1120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs901609668; called by muse, mutect2
- KHNYN | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 399/958 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52162764; called by muse, mutect2, varscan2
- PCDHB10 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 584/1733 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs781947513, COSV53377622; called by muse, mutect2, varscan2
- PRRC2A | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 66/844 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs755147720, COSV63224878; called by muse, mutect2
- RIC8A | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 44/804 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs771100292; called by muse, mutect2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 61/986 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- TAF4 | c.2042A>G p.Q681R | Missense Mutation (SNP) | VAF 50/916 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1379651588; called by muse, mutect2
- TECTA | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 88/1102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1180694694; called by muse, mutect2
- TEP1 | c.1709A>G p.H570R | Missense Mutation (SNP) | VAF 30/515 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1330277970; called by muse, mutect2
- UTRN | c.6835C>T p.R2279C | Missense Mutation (SNP) | VAF 435/1875 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs114254210, COSV62340532; called by muse, varscan2
- ACY3 | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 20/656 reads (3%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.452); called by muse, mutect2
- ADGRV1 | c.13002T>G p.H4334Q | Missense Mutation (SNP) | VAF 116/3204 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- BMS1 | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 433/1433 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DGKK | c.3301C>T p.H1101Y | Missense Mutation (SNP) | VAF 63/1456 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 118/3168 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- LAMC3 | c.2834A>T p.Q945L | Missense Mutation (SNP) | VAF 28/703 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2
- MXRA5 | c.7456C>A p.L2486M | Missense Mutation (SNP) | VAF 42/641 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH1 | c.1510T>G p.Y504D | Missense Mutation (SNP) | VAF 138/1486 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PARP8 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 56/1785 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- PTCH2 | c.339_340del p.Q113Hfs*31 | Frame Shift Del (DEL) | VAF 204/604 reads (34%) | called by pindel, varscan2
- RAG2 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 420/1992 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMURF2 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 312/1768 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.18); called by muse, varscan2
- TRPS1 | c.3244C>A p.P1082T (on ENST00000220888 / NM_001330599.2; = p.P1095T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 1982/2229 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNB4 | c.639C>T p.Y213= | Silent (SNP) | VAF 115/2174 reads (5%) | catalogued as rs753811632, COSV99138029; called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as rs1167537044; called by muse, mutect2
- EN1 | c.486G>A p.R162= | Silent (SNP) | VAF 35/239 reads (15%) | catalogued as rs1353779175; called by muse, mutect2, varscan2
- FBXO39 | c.549C>A p.L183= | Silent (SNP) | VAF 466/1059 reads (44%) | called by muse, mutect2, varscan2
- LRP5 | c.1695C>T p.R565= | Silent (SNP) | VAF 42/629 reads (7%) | catalogued as rs1309853369; called by muse, mutect2
- MEP1B | c.1047C>G p.G349= | Silent (SNP) | VAF 64/1686 reads (4%) | called by muse, mutect2
- SDR16C5 | c.384C>T p.I128= | Silent (SNP) | VAF 114/756 reads (15%) | catalogued as rs377080872; called by muse, mutect2, varscan2
- ZNF668 | c.1464T>C p.D488= | Silent (SNP) | VAF 21/412 reads (5%) | called by muse, mutect2
- C7orf57 | c.241+85T>C | Intron (SNP) | VAF 33/457 reads (7%) | called by muse, mutect2
- CSKMT | c.-35T>G | 5'UTR (SNP) | VAF 44/173 reads (25%) | catalogued as rs199880114; called by muse, mutect2, varscan2
- ETS2 | c.-150-66A>T | Intron (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- MYCBPAP | c.-8G>C | 5'UTR (SNP) | VAF 62/840 reads (7%) | called by muse, mutect2
- NCR1 | c.*85C>T | 3'UTR (SNP) | VAF 65/112 reads (58%) | catalogued as rs561654531; called by muse, mutect2, varscan2
- NFIB | c.*15A>G | 3'UTR (SNP) | VAF 204/4324 reads (5%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 30/582 reads (5%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 88/735 reads (12%) | called by muse, varscan2
- SLC1A6 | c.935+15G>T | Intron (SNP) | VAF 58/389 reads (15%) | called by muse, mutect2, varscan2
- TRIM22 | c.520-75C>G | Intron (SNP) | VAF 26/190 reads (14%) | catalogued as COSV66091415; called by muse, mutect2
- TTR | c.200+47G>A | Intron (SNP) | VAF 327/602 reads (54%) | catalogued as rs200811834; called by muse, mutect2, varscan2
